Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0RY, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0RY-01A (Primary Tumor).

100-0-3

Adenocarcinoma, endometrioid, NOS 8380/3

Site: endometrium C54.1

lw
10/27/11

FINAL DIAGNOSIS:

PART 1: OVARY AND FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY -
BENIGN OVARY AND FALLOPIAN TUBE.

PART 2: OVARY AND FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY -
A. FIBROMA OF LEFT OVARY.
B. RESIDUAL OVARY WITH PHYSIOLOGICAL CHANGES.
C. BENIGN FALLOPIAN TUBE.

PART 3: UTERUS AND CERVIX, TOTAL ABDOMINAL HYSTERECTOMY (226 GRAMS) -
A. ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE.
B. NUCLEAR GRADE 2, FIGO GRADE II.
C. THE TUMOR INVADES 96% OF THE MYOMETRIAL THICKNESS (2.5 CM INVASION OF 2.6 CM THICK MYOMETRIUM).
D. NO ENDOCERVICAL INVASION IS IDENTIFIED.
E. NO LYMPHOVASCULAR SPACE INVASION IS IDENTIFIED.
F. THE BACKGROUND ENDOMETRIUM IS ATROPHIC.
G. THE MYOMETRIUM SHOWS ADENOMYOSIS AND LEIOMYOMA.
H. CHRONIC CERVICITIS WITH NABOTHIAN CYSTS AND TUNNEL CLUSTERS.
I. PELVIC WASHING IS NEGATIVE FOR TUMOR CELLS.
J. STAGE pT1b N0 MX.

PART 4: LYMPH NODES, RIGHT PELVIC, DISSECTION -
FIVE LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/5).

PART 5: LYMPH NODES, RIGHT COMMON ILIAC, DISSECTION -
THREE LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/3).

PART 6: LYMPH NODES, LEFT PELVIC, DISSECTION -
ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 7: HERNIA SAC, EXCISION -
MESOTHELIUM-LINED FIBROADIPOSE TISSUE, CONSISTENT WITH HERNIA SAC.

lw 10/27/11

Source: NCI Genomic Data Commons file 7fcc0a94-e263-49f2-b590-bb49dcc9f25e (TCGA-BG-A0RY.170B34D7-94B3-4129-9B4D-E36AF7A09897.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).